Gene-level copy-number profile of tumor specimen TCGA-EE-A2MT-06A from TCGA case TCGA-EE-A2MT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 47.5 years (17,332 days).
Specimen TCGA-EE-A2MT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.22d67ce5-ef99-4c70-805c-8732cc38c416.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-EE-A2MT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/1e18bf5f-f67e-4731-864a-e110044d5d6f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 5,403; copy number 2: 49,577; copy number 3: 2,159; copy number 4: 1,274; copy number 5: 1,377; copy number 25: 5; copy number 30: 5; copy number 35: 17; copy number 39: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-EE-A2MT-06A-11D-A191-01): tumor purity 0.88, ploidy 2.04, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,406 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:158,131,983–200,860,704, 815 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr1:213,428,708–241,916,543, 562 genes, copy number 5 (broad region; genes not listed).
- chr6:63,227,485–65,707,226, 22 genes, copy number 25–35 (within-gene range 2–35): SPTLC1P3, AL450346.2, LGSN, AL121949.3, AL121949.2, AL121949.1, EEF1B2P5, PTP4A1, RPL7AP34, AL135905.1, AL135905.2, AL513043.1, RPL9P18, PHF3, EYS, AL354719.1, SCAT8, GCNT1P4, AL357375.1, HNRNPDP2, AL355357.1, AL365217.1.
- chr6:66,710,242–67,625,464, 7 genes, copy number 30–39: AL450336.1, RNU7-66P, AL591004.1, AL365503.1, RNA5SP208, RNU6-280P, Y_RNA.

Autosomal genes at a single copy (total copy number 1): 3,016. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
